Somatic mutation profile of tumor specimen 0DXJHW from CCDI case PBCRKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.5 years (3,461 days).
Specimen 0DXJHW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 438a5846-144e-4178-8663-6c18b2f5dd3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJEJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24c18602-df0c-4142-8d36-17b5f9712237

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 2, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.2504_2508del p.Y835Sfs*14 | Frame Shift Del (DEL) | VAF 67/171 reads (39%) | catalogued as rs886040982; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 97/223 reads (43%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AVPR1B | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 211/626 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs370119322; called by muse, mutect2, varscan2
- CHAF1B | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 135/421 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1292655191; called by muse, mutect2, varscan2
- ZNF646 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 232/387 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs767200695; called by muse, mutect2, varscan2
- ASTN1 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 198/646 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL19A1 | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 306/559 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRAXIN | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 189/602 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCGBP | c.5266G>T p.V1756L | Missense Mutation (SNP) | VAF 233/439 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); called by muse, varscan2
- IL18RAP | c.210C>A p.H70Q | Missense Mutation (SNP) | VAF 321/883 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL1F10 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 334/935 reads (36%) | called by muse, mutect2, varscan2
- MUC5B | c.10909A>T p.S3637C | Missense Mutation (SNP) | VAF 244/1001 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV1 | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 226/713 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OR6N1 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 258/759 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWC2 | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 207/486 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDHR5 | c.1365G>A p.E455= | Silent (SNP) | VAF 187/599 reads (31%) | catalogued as rs1264942906; called by muse, mutect2, varscan2
- SCP2 | c.1206C>T p.L402= | Silent (SNP) | VAF 325/910 reads (36%) | catalogued as rs374084722; called by muse, mutect2, varscan2
- THUMPD3 | c.1437T>A p.V479= | Silent (SNP) | VAF 318/635 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.41826G>A p.K13942= (on ENST00000591111; = p.K6518= on NM_003319.4) | Silent (SNP) | VAF 243/718 reads (34%) | catalogued as rs1460478978; called by muse, mutect2, varscan2
- RPH3AL | c.-37+2240T>C | Intron (SNP) | VAF 224/363 reads (62%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.*1888_*1889insGTG | 3'UTR (INS) | VAF 9/298 reads (3%) | called by mutect2, pindel*
- TSC2 | c.1444-13T>A | Intron (SNP) | VAF 163/373 reads (44%) | called by muse, mutect2, varscan2
